Surgical pathology report (de-identified scan), TCGA case TCGA-G2-A2EJ, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site MD Anderson, specimen TCGA-G2-A2EJ-01A (Primary Tumor).

PATHOLOGY REPORT

1CD-0-3

carcinoma, urothelial, NOS 8/20/3

Site: bladder, NOS C629

hw
5/31/11

A) BLADDER TUMOR:

UROTHELIAL CARCINOMA WITH EXTENSIVE SQUAMOUS
DIFFERENTIATION, HIGH GRADE (GRADE 3),

INVASIVE INTO MUSCULARIS PROPRIA.

No lymphovascular invasion evident.

GROSS DESCRIPTION

(A) BLADDER TUMOR - Multiple fragments of white-tan soft tissue (4.0 x 4.0 x 2.5 cm in aggregate). About 75% of specimen submitted in A1-A10.

CLINICAL HISTORY

Bladder carcinoma.

hw 5/31/11

Source: NCI Genomic Data Commons file feaccd1c-0cba-447b-a950-cf0275016ce7 (TCGA-G2-A2EJ.2C46A6D2-74EE-4389-9D8F-4737CE4832FB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).